Gene-level copy-number profile of tumor specimen ALCH-B3DE-TTP1-A from ALCHEMIST case ALCH-B3DE, project ALCHEMIST-ALCH (Adjuvant Lung Cancer Enrichment Marker Identification and Sequencing Trial). Sex at birth: female; Primary diagnosis: Adenocarcinoma, NOS; Age at diagnosis: 58.3 years (21,294 days).
Specimen ALCH-B3DE-TTP1-A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file b1b6cd06-4a15-490b-b17e-8c846ca4a12f.wgs.ASCAT.gene_level.copy_number_variation.tsv, workflow AscatNGS on whole-genome sequencing of the tumor/normal pair, germline comparator ALCH-B3DE-NB1-A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 2,228 have no estimate.
https://portal.gdc.cancer.gov/files/e9b69656-d4bd-4c22-a0ca-549f008bce5f

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 0: 66; copy number 1: 1,025; copy number 2: 56,794; copy number 3: 467; copy number 4: 31; copy number 5: 6; copy number 6: 3; copy number 7: 1; copy number 8: 1; copy number 14: 1.

Homozygous deletions (total copy number 0; autosomes only): 66 genes in 18 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr1:31,727,117–31,764,893, 2 genes: ADGRB2, MIR4254.
- chr1:47,432,133–47,440,691, 2 genes: FOXD2-AS1, FOXD2.
- chr3:49,689,538–49,723,973, 3 genes: RNF123, AMIGO3, GMPPB.
- chr8:11,576,257–11,582,817, 1 gene: LINC00208.
- chr8:101,686,547–101,689,093, 1 gene (within-gene range 0–2): AP000426.1.
- chr9:123,356,170–123,380,324, 1 gene (within-gene range 0–2): CRB2.
- chr9:123,402,525–123,402,603, 1 gene (within-gene range 0–2): MIR601.
- chr9:125,372,325–125,417,586, 2 genes: AL627223.1, Metazoa_SRP.
- chr9:130,400,266–130,400,565, 1 gene (within-gene range 0–2): RN7SL665P.
- chr10:133,160,219–133,226,412, 1 gene: KNDC1.
- chr15:25,176,832–25,249,279, 40 genes (within-gene range 0–2): SNORD115-4, SNORD115-5, SNORD115-6, SNORD115-7, SNORD115-8, SNORD115-9, SNORD115-10, SNORD115-11, SNORD115-12, SNORD115-13, SNORD115-14, SNORD115-15, SNORD115-16, SNORD115-17, SNORD115-18, SNORD115-19, SNORD115-20, SNORD115-21, SNORD115-22, SNORD115-23, SNORD115-24, SNORD115-25, SNORD115-26, SNORD115-27, SNORD115-28, SNORD115-29, SNORD115-30, SNORD115-31, SNORD115-32, SNORD115-33, SNORD115-34, SNORD115-35, SNORD115-36, SNORD115-37, SNORD115-38, SNORD115-39, SNORD115-40, SNORD115-41, SNORD115-42, SNORD115-43.
- chr15:76,976,915–77,037,475, 3 genes: RN7SL278P, KRT8P23, PSTPIP1.
- chr16:1,770,286–1,771,730, 1 gene (within-gene range 0–2): NME3.
- chr17:41,523,617–41,528,308, 1 gene: KRT19.
- chr17:63,430,468–63,455,817, 3 genes (within-gene range 0–2): AC005828.4, CYB561, AC005828.5.
- chr17:63,477,061–63,498,380, 1 gene (within-gene range 0–2): ACE.
- chr17:83,104,255–83,106,910, 1 gene: AC144831.1.
- chr19:12,643,275–12,643,919, 1 gene (within-gene range 0–2): RPL10P16.

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): 12 genes in 8 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr1:143,720,510–143,720,644, 1 gene, copy number 7: RNVU1-23.
- chr7:102,473,118–102,517,777, 2 genes, copy number 5 (within-gene range 2–5): POLR2J, RASA4B.
- chr14:104,857,792–104,858,836, 1 gene, copy number 14: AL583810.1.
- chr15:65,001,512–65,029,639, 2 genes, copy number 5: MTFMT, AC013553.2.
- chr17:83,220,527–83,240,804, 2 genes, copy number 5: AC139099.1, RPL23AP87.
- chr21:43,092,956–43,107,570, 1 gene, copy number 6: U2AF1.
- chr21:43,115,334–43,141,092, 2 genes, copy number 6: MRPL51P2, FRGCA.
- chr22:21,466,423–21,471,269, 1 gene, copy number 8: TMEM191C.

Autosomal genes at a single copy (total copy number 1): 1,025. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
